Somatic mutation profile of tumor specimen TCGA-CV-7423-01A (aliquot TCGA-CV-7423-01A-11D-2078-08) from TCGA case TCGA-CV-7423, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Overlapping lesion of lip, oral cavity and pharynx; AJCC pathologic stage: Stage II; Tumor grade: G1; Age at diagnosis: 65.9 years (24,071 days).
Specimen TCGA-CV-7423-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84990be3-b6a2-466f-9ae5-f719f07b1b43.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CV-7423-10A (Blood Derived Normal), aliquot TCGA-CV-7423-10A-01D-2078-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2daeed7b-703b-433c-90d0-dbe9be5c6fe0

The open-access MAF lists 78 somatic variants for this specimen: 55 protein-altering or splice-affecting, 21 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 41, Silent 21, Nonsense Mutation 5, In Frame Del 4, Intron 2, Frame Shift Ins 2, Splice Site 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1015G>T p.E339* | Nonsense Mutation (SNP) | VAF 5/17 reads (29%) | catalogued as rs17882252, CM984588, COSV52705645, COSV52980241, COSV53040770, COSV53664260; ClinVar: pathogenic; called by muse, mutect2
- ACO1 | c.1046C>T p.P349L | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.024); catalogued as COSV100008360; called by muse, mutect2, varscan2
- ADGRE3 | c.1121C>A p.A374E | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99506456; called by muse, varscan2
- AL662899.2 | c.76G>C p.D26H | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.946); catalogued as COSV100789028; called by muse, mutect2, varscan2
- ATP8A1 | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.772); catalogued as COSV52533139; called by muse, mutect2, varscan2
- BRINP3 | c.647G>A p.G216D | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66542484; called by muse, mutect2, varscan2
- CCDC170 | c.92C>T p.T31M | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.855); catalogued as rs1159721192, COSV53339314, COSV53340316; called by muse, mutect2
- CHRM3 | c.447C>A p.Y149* | Nonsense Mutation (SNP) | VAF 26/61 reads (43%) | catalogued as COSV55095565, COSV99698946; called by muse, mutect2, varscan2
- CHST15 | c.878A>G p.K293R | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.404); catalogued as COSV100655246; called by muse, mutect2, varscan2
- CLASRP | c.181G>C p.E61Q | Missense Mutation (SNP) | VAF 4/60 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99673980; called by muse, mutect2
- CNTN6 | c.2179_2181del p.E727del | In Frame Del (DEL) | VAF 12/36 reads (33%) | catalogued as rs1321539790; called by pindel, varscan2
- COQ8A | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT deleterious (0.04); PolyPhen benign (0.018); catalogued as rs148376283; called by muse, mutect2, varscan2
- CORO2B | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0.189); catalogued as rs543637910, COSV55955115, COSV99962909; called by muse, mutect2
- DGKK | c.3293T>A p.I1098N | Missense Mutation (SNP) | VAF 7/12 reads (58%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.656); catalogued as COSV101053116; called by muse, mutect2, varscan2
- DPPA4 | c.571A>C p.T191P | Missense Mutation (SNP) | VAF 45/83 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.796); catalogued as COSV100169567; called by muse, mutect2, varscan2
- EIF4B | c.148G>C p.D50H | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.667); catalogued as COSV100016899; called by muse, mutect2, varscan2
- ELN | c.1464_1481del p.V491_G496del | In Frame Del (DEL) | VAF 45/264 reads (17%) | catalogued as rs782444521; called by mutect2, varscan2
- ERAP1 | c.1840G>A p.D614N | Missense Mutation (SNP) | VAF 4/59 reads (7%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV99701123; called by muse, mutect2
- EVI5 | c.740G>A p.S247N | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV100789687; called by muse, mutect2, varscan2
- FBLN1 | c.631G>C p.G211R | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.559); catalogued as COSV99411026; called by muse, mutect2, varscan2
- GLO1 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV100974104; called by muse, varscan2
- GRAMD1C | c.165G>C p.W55C | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1559774784; called by muse, mutect2
- HAUS8 | c.926G>A p.R309Q | Missense Mutation (SNP) | VAF 16/101 reads (16%) | SIFT tolerated (0.83); PolyPhen benign (0.009); catalogued as rs747503889, COSV53727194, COSV99505429; called by muse, mutect2, varscan2
- HPX | c.1226T>C p.M409T | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99793431; called by muse, mutect2, varscan2
- ISLR2 | c.1666C>T p.R556C | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.563); catalogued as COSV100679563, COSV100679681; called by muse, mutect2
- KLHL4 | c.1110C>A p.Y370* | Nonsense Mutation (SNP) | VAF 12/53 reads (23%) | catalogued as COSV100909557, COSV100910009; called by muse, mutect2, varscan2
- MS4A14 | c.468+2T>C p.X156_splice | Splice Site (SNP) | VAF 21/81 reads (26%) | catalogued as COSV100280586; called by muse, mutect2, varscan2
- MTA2 | c.1782G>C p.Q594H | Missense Mutation (SNP) | VAF 8/60 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.36); catalogued as COSV53471590, COSV99545467; called by muse, varscan2
- MUC17 | c.4180G>T p.G1394* | Nonsense Mutation (SNP) | VAF 95/381 reads (25%) | catalogued as COSV100074263; called by muse, mutect2, varscan2
- NFRKB | c.1507C>T p.R503W (on ENST00000446488 / NM_001143835.2; = p.R528W on NM_006165.3) | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs764142634, COSV100451810; called by muse, mutect2, varscan2
- PADI6 | c.1922G>A p.C641Y | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100639973; called by muse, mutect2, varscan2
- PHLDA2 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 11/20 reads (55%) | SIFT tolerated (1); PolyPhen benign (0.148); catalogued as rs755568865, COSV100045282; called by muse, mutect2, varscan2
- PSD4 | c.1178C>T p.S393F | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as COSV99831295; called by muse, mutect2, varscan2
- PUS7L | c.1535A>T p.E512V | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.243); catalogued as COSV100786573; called by muse, mutect2, varscan2
- SCN2A | c.122G>A p.R41H | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as rs754993031, COSV51849102; called by muse, mutect2, varscan2
- SETD9 | c.283C>A p.Q95K | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as COSV99605670; called by muse, mutect2, varscan2
- SLC17A6 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.61); PolyPhen benign (0.03); catalogued as rs199699968, COSV54136138; called by muse, mutect2, varscan2
- SLC34A1 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.54); PolyPhen benign (0.006); catalogued as rs200137299; called by muse, mutect2, varscan2
- SOGA3 | c.2260G>A p.E754K | Missense Mutation (SNP) | VAF 13/104 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.339); catalogued as rs867523897, COSV64106169; called by muse, mutect2, varscan2
- TPCN2 | c.175-2A>G p.X59_splice | Splice Site (SNP) | VAF 7/34 reads (21%) | catalogued as COSV53729486; called by muse, mutect2, varscan2
- TRA2B | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0); catalogued as rs1254689753, COSV52025033; called by muse, mutect2, varscan2
- TTC27 | c.1904A>G p.Y635C | Missense Mutation (SNP) | VAF 11/64 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.973); catalogued as COSV100513322; called by muse, mutect2, varscan2
- TTN | c.59318G>A p.R19773H (on ENST00000591111; = p.R12349H on NM_003319.4) | Missense Mutation (SNP) | VAF 27/106 reads (25%) | PolyPhen benign (0.007); catalogued as rs727504690, COSV60241453; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTN | c.10444G>A p.E3482K (on ENST00000591111; = p.E3436K on NM_003319.4) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | catalogued as COSV60166593; called by muse, mutect2, varscan2
- UPF2 | c.3624G>C p.E1208D | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as COSV100707360; called by muse, mutect2, varscan2
- ZC3H3 | c.1664C>G p.P555R | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.024); catalogued as COSV52787565, COSV99368169, COSV99368231; called by muse, mutect2, varscan2
- ZFAT | c.772A>G p.M258V | Missense Mutation (SNP) | VAF 55/100 reads (55%) | SIFT tolerated (0.07); PolyPhen benign (0.095); catalogued as rs1004091784, COSV100914784; called by muse, mutect2, varscan2
- ZNF423 | c.709C>T p.R237C (on ENST00000563137 / NM_001379286.1; = p.R229C on NM_015069.4) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52177905; called by muse, mutect2, varscan2
- ZNF516 | c.49C>T p.P17S | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.895); catalogued as COSV101487326; called by muse, mutect2, varscan2
- CMTM5 | c.352C>T p.Q118* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | called by muse, mutect2
- DOCK8 | c.5728_5729dup p.E1911Mfs*10 | Frame Shift Ins (INS) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- HCRTR1 | c.136_138del p.E46del | In Frame Del (DEL) | VAF 25/125 reads (20%) | called by mutect2, pindel, varscan2
- LZTS3 | c.1287del p.D430Tfs*6 (on ENST00000329152; = p.D384Tfs*6 on NM_001282533.2) | Frame Shift Del (DEL) | VAF 19/54 reads (35%) | called by mutect2, pindel, varscan2
- RTN4 | c.3341dup p.D1114Efs*4 (on ENST00000337526 / NM_020532.5; = p.D121Efs*4 on NM_007008.3) | Frame Shift Ins (INS) | VAF 6/41 reads (15%) | called by mutect2, pindel, varscan2
- SPATA31D1 | c.1531_1539del p.H511_E513del | In Frame Del (DEL) | VAF 11/39 reads (28%) | called by mutect2, pindel, varscan2
- ACTL6B | c.567C>T p.I189= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs772895278, COSV99355542; called by muse, mutect2, varscan2
- ANXA9 | c.879G>A p.L293= | Silent (SNP) | VAF 14/180 reads (8%) | catalogued as COSV56498101; called by muse, mutect2
- CGNL1 | c.657C>T p.C219= | Silent (SNP) | VAF 20/155 reads (13%) | catalogued as rs1440918108, COSV99848681; called by muse, mutect2, varscan2
- CSF1 | c.69C>T p.V23= | Silent (SNP) | VAF 16/47 reads (34%) | catalogued as COSV100294712; called by muse, mutect2, varscan2
- DNAH8 | c.150C>G p.L50= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV100546382; called by muse, mutect2
- ELK4 | c.390G>A p.Q130= | Silent (SNP) | VAF 5/47 reads (11%) | catalogued as COSV99222450; called by mutect2, varscan2
- FBXO43 | c.1650C>T p.I550= | Silent (SNP) | VAF 18/40 reads (45%) | catalogued as COSV101413892; called by muse, mutect2, varscan2
- FMN2 | c.4335C>A p.P1445= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as COSV100146299; called by muse, mutect2, varscan2
- GPR4 | c.150C>T p.N50= | Silent (SNP) | VAF 18/67 reads (27%) | catalogued as COSV59916756, COSV59917393, COSV59917617; called by muse, mutect2, varscan2
- HELZ2 | c.6804C>T p.S2268= (on ENST00000467148 / NM_001037335.2; = p.S1699= on NM_033405.3) | Silent (SNP) | VAF 42/106 reads (40%) | catalogued as COSV100918813; called by muse, mutect2, varscan2
- IMMP2L | c.438C>T p.A146= | Silent (SNP) | VAF 7/56 reads (13%) | catalogued as COSV100071991; called by muse, mutect2, varscan2
- KCNJ4 | c.324G>A p.P108= | Silent (SNP) | VAF 15/39 reads (38%) | catalogued as rs778653465, COSV57859210; called by muse, mutect2, varscan2
- MINDY2 | c.537C>T p.F179= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as COSV100376493, COSV57505163; called by muse, mutect2, varscan2
- NID1 | c.2166G>A p.G722= | Silent (SNP) | VAF 19/120 reads (16%) | catalogued as rs779547966, COSV51624369; called by muse, mutect2, varscan2
- PCDHA7 | c.1506C>T p.R502= | Silent (SNP) | VAF 15/96 reads (16%) | catalogued as COSV100971648; called by muse, mutect2, varscan2
- PUS7L | c.201T>C p.F67= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100786574, COSV61261600; called by muse, mutect2
- TBC1D10C | c.282G>A p.P94= | Silent (SNP) | VAF 14/56 reads (25%) | catalogued as rs200017820, COSV56702030; called by muse, mutect2, varscan2
- TGM5 | c.807C>G p.G269= (on ENST00000220420 / NM_201631.4; = p.G187= on NM_004245.4) | Silent (SNP) | VAF 12/65 reads (18%) | catalogued as COSV99589143; called by muse, mutect2, varscan2
- TUB | c.1515C>T p.C505= (on ENST00000299506 / NM_177972.3; = p.C560= on NM_003320.4) | Silent (SNP) | VAF 15/24 reads (63%) | catalogued as rs199733844; ClinVar: uncertain significance; called by mutect2, varscan2
- UBL7 | c.969G>A p.Q323= | Silent (SNP) | VAF 22/137 reads (16%) | catalogued as COSV100795426; called by muse, mutect2, varscan2
- ZC3H7B | c.2673C>G p.L891= | Silent (SNP) | VAF 7/50 reads (14%) | catalogued as COSV100687528; called by muse, mutect2, varscan2
- MACF1 | c.15832-9964T>C | Intron (SNP) | VAF 6/45 reads (13%) | catalogued as COSV99245683; called by muse, mutect2, varscan2
- PXN | c.831+1581C>T | Intron (SNP) | VAF 7/12 reads (58%) | catalogued as rs1240212416; called by muse, mutect2, varscan2
